Somatic mutation profile of tumor specimen 0DEQX1 from CCDI case PBBRDV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.9 years (4,332 days).
Specimen 0DEQX1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2556182d-bc91-4f45-a453-bf297990e7f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEQXQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ca4e329-80bf-4a29-b7fd-44e5ff221c42

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Nonsense Mutation 2, 5'UTR 1, Silent 1, Intron 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1636A>G p.N546D (on ENST00000447712 / NM_023110.3; = p.N544D on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519898, COSV58330676; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 132/421 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 56/319 reads (18%) | catalogued as rs397514641, CM000774, COSV62197492; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 53/369 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 68/477 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs752016285, COSV52146942, COSV52147138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPQ | c.1186A>G p.N396D | Missense Mutation (SNP) | VAF 40/512 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as rs933794332; called by muse, mutect2
- FAM25C | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 19/609 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.923); catalogued as rs566948491, COSV100714518; called by muse, mutect2
- KRTAP1-5 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 72/289 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.573); catalogued as rs1305185612; called by muse, mutect2, varscan2
- MST1R | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs759008251, COSV56569977; called by muse, mutect2, varscan2
- NF1 | c.7481G>A p.W2494* (on ENST00000358273 / NM_001042492.3; = p.W2473* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 22/328 reads (7%) | catalogued as CM143477, COSV62210165; called by muse, mutect2
- PCDHA6 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100971530, COSV65348503; called by muse, mutect2
- ARHGAP30 | c.1615G>C p.A539P | Missense Mutation (SNP) | VAF 65/295 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- ASIC1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C4orf54 | c.5072C>T p.A1691V | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); called by muse, mutect2
- NF1 | c.7322-2A>G p.X2441_splice (on ENST00000358273 / NM_001042492.3; = p.X2420_splice on NM_000267.3) | Splice Site (SNP) | VAF 101/371 reads (27%) | called by muse, mutect2, varscan2
- RNF41 | c.282C>T p.V94= | Silent (SNP) | VAF 42/314 reads (13%) | called by muse, varscan2
- ASIC1 | c.-13C>G | 5'UTR (SNP) | VAF 29/119 reads (24%) | called by muse, varscan2
- KSR2 | c.*91C>G | 3'UTR (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- TBC1D30 | c.644-2860C>T | Intron (SNP) | VAF 35/291 reads (12%) | called by muse, mutect2, varscan2
